Somatic mutation profile of tumor specimen TCGA-CC-5264-01A (aliquot TCGA-CC-5264-01A-01D-A12Z-10) from TCGA case TCGA-CC-5264, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 71.1 years (25,979 days).
Specimen TCGA-CC-5264-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db1f643f-7e41-4929-bb98-ca8889ad554d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5264-10A (Blood Derived Normal), aliquot TCGA-CC-5264-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc118c20-68de-4d74-b5a7-304e78795fa7

The open-access MAF lists 104 somatic variants for this specimen: 78 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 8, Intron 3, Splice Site 3, Frame Shift Del 2, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.3963+2T>G p.X1321_splice | Splice Site (SNP) | VAF 53/119 reads (45%) | catalogued as rs397508650, CS034838, COSV50043278; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM17 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60397928; called by muse, mutect2, varscan2
- ADAM18 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV55844966; called by muse, mutect2, varscan2
- ADRA1D | c.1661C>A p.A554D | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV101062845, COSV65242219; called by muse, mutect2, varscan2
- ADRA1D | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1195126550, COSV65240425; called by muse, mutect2, varscan2
- ARNT2 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 138/167 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57582585; called by muse, mutect2, varscan2
- B9D2 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54683738; called by mutect2, varscan2
- BMP7 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV67779888; called by muse, mutect2, varscan2
- C9 | c.1252A>G p.S418G | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as rs1156696518, COSV54675050; called by muse, mutect2, varscan2
- CADPS | c.3160A>T p.I1054L | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780894973, COSV51871096; called by muse, mutect2, varscan2
- CCDC6 | c.804A>C p.E268D | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54055338; called by muse, mutect2, varscan2
- CHD5 | c.4798G>T p.D1600Y | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV99312536; called by muse, varscan2
- CRB2 | c.2490C>A p.H830Q | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV63502185; called by muse, mutect2, varscan2
- DCAF4L2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 250/509 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60477129; called by muse, mutect2, varscan2
- DENND6A | c.237+1G>T p.X79_splice | Splice Site (SNP) | VAF 25/40 reads (63%) | catalogued as COSV100231272; called by muse, mutect2, varscan2
- DENND6A | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV100231274; called by muse, mutect2, varscan2
- DHRS3 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV66107746; called by muse, mutect2, varscan2
- DNAH17 | c.12961T>A p.W4321R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53143924; called by muse, mutect2, varscan2
- ERAP2 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 132/155 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65938993; called by muse, mutect2, varscan2
- EXO1 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV62216730; called by muse, mutect2, varscan2
- FAM124B | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs901948091, COSV54740399; called by muse, mutect2, varscan2
- FAM20A | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV56835922; called by muse, mutect2, varscan2
- FASN | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60751552; called by mutect2, varscan2
- FBXO42 | c.2030G>T p.S677I | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65044701; called by muse, mutect2, varscan2
- GABRA4 | c.1499C>A p.S500* | Nonsense Mutation (SNP) | VAF 58/90 reads (64%) | catalogued as COSV51924088; called by muse, mutect2, varscan2
- GJC1 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57910639; called by muse, mutect2, varscan2
- HOXC8 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50000589, COSV50002386; called by muse, mutect2, varscan2
- IFI16 | c.1457A>T p.Q486L | Missense Mutation (SNP) | VAF 172/1392 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV55531989; called by muse, varscan2
- KCNA1 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV101230324, COSV66836762; called by muse, varscan2
- KIAA1109 | c.13081G>C p.A4361P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52665254, COSV99145411; called by muse, mutect2, varscan2
- KIT | c.2427T>A p.C809* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV55392182; called by muse, mutect2, varscan2
- KRT6C | c.1513A>T p.S505C | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52876817; called by muse, mutect2, varscan2
- LAMB3 | c.3280C>T p.Q1094* | Nonsense Mutation (SNP) | VAF 201/581 reads (35%) | catalogued as COSV50520487; called by muse, mutect2, varscan2
- LAMC3 | c.3370T>A p.S1124T | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV63089256; called by muse, mutect2, varscan2
- LRP1B | c.9070G>A p.E3024K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.76); catalogued as COSV67196694, COSV67245535; called by muse, mutect2, varscan2
- LRPPRC | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 28/600 reads (5%) | catalogued as COSV53235262; called by muse, mutect2
- LRRC45 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs750882545, COSV60710576; called by muse, mutect2, varscan2
- MAP4K5 | c.1072A>G p.M358V | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV50152969; called by muse, mutect2, varscan2
- MASP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV68896203; called by muse, mutect2, varscan2
- MBD3 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50083122; called by muse, mutect2, varscan2
- MCM10 | c.2027C>T p.T676I (on ENST00000484800 / NM_182751.3; = p.T675I on NM_018518.5) | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1405888729, COSV66333385; called by muse, mutect2, varscan2
- MORF4L2 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 195/206 reads (95%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV64610774; called by muse, mutect2, varscan2
- MUC5B | c.6380G>A p.S2127N | Missense Mutation (SNP) | VAF 96/680 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1403730092, COSV101500037; called by muse, mutect2, varscan2
- NCOR2 | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs888041970, COSV62294837; called by muse, mutect2, varscan2
- NLRP2 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 115/221 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV54753094, COSV54756876; called by muse, mutect2, varscan2
- NRCAM | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV61032692; called by muse, mutect2, varscan2
- NSD2 | c.2824G>T p.G942W | Missense Mutation (SNP) | VAF 92/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56387765, COSV56391074; called by muse, mutect2, varscan2
- NUAK2 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.275); catalogued as COSV65681005; called by muse, mutect2, varscan2
- OPRK1 | c.443C>G p.T148S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55568978; called by muse, mutect2, varscan2
- OR10A2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as COSV56298905; called by muse, mutect2, varscan2
- OR5L1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 100/775 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61733045; called by muse, mutect2, varscan2
- OTOF | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as COSV55498199, COSV55502880; called by muse, mutect2, varscan2
- PLS1 | c.933A>T p.K311N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV61833087; called by muse, mutect2, varscan2
- PNPLA8 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs768754573, COSV57551738; called by muse, mutect2, varscan2
- POTEH | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 101/626 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs754645789, COSV100624678; called by mutect2, varscan2
- PPP2R5D | c.1747A>C p.K583Q | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV55144419; called by muse, mutect2, varscan2
- PRDM16 | c.3095A>T p.H1032L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV54582178, COSV54611120; called by muse, mutect2, varscan2
- PREX2 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55757142; called by muse, mutect2, varscan2
- RANBP17 | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs765324653, COSV66645919; called by muse, mutect2, varscan2
- RBM8A | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 172/455 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57162004; called by muse, mutect2, varscan2
- RCC1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 130/233 reads (56%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as rs547058163, COSV65779005; called by muse, mutect2, varscan2
- SBSN | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 195/345 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV71733077; called by muse, mutect2, varscan2
- SEM1 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV50350866, COSV50351560; called by muse, mutect2, varscan2
- SH3TC2 | c.1057G>T p.G353* | Nonsense Mutation (SNP) | VAF 122/142 reads (86%) | catalogued as COSV60461661; called by muse, mutect2, varscan2
- SRGAP3 | c.2024G>A p.C675Y | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV64531328; called by muse, mutect2, varscan2
- SRM | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 93/308 reads (30%) | catalogued as COSV65384495; called by muse, mutect2, varscan2
- TACC1 | c.1322G>C p.C441S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV52522352; called by muse, mutect2
- TLR7 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 76/88 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV66123745; called by muse, mutect2, varscan2
- TMEM82 | c.875T>A p.L292H | Missense Mutation (SNP) | VAF 103/354 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65387107; called by muse, mutect2, varscan2
- TSNAXIP1 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54648508; called by muse, mutect2, varscan2
- ZFYVE26 | c.5321-1G>A p.X1774_splice | Splice Site (SNP) | VAF 64/81 reads (79%) | catalogued as COSV61325451; called by muse, mutect2, varscan2
- ZIK1 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56736630; called by muse, mutect2, varscan2
- ZMAT4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as rs1273063811, COSV52692657; called by muse, mutect2, varscan2
- ZNF565 | c.1126G>T p.E376* (on ENST00000355114; = p.E336* on NM_152477.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as COSV104412336, COSV58410497; called by muse, mutect2, varscan2
- ZNF668 | c.1609T>A p.S537T | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56212222; called by muse, mutect2, varscan2
- GSE1 | c.483_484del p.L162Pfs*188 | Frame Shift Del (DEL) | VAF 101/152 reads (66%) | called by mutect2, pindel, varscan2
- PLCG1 | c.988dup p.W330Lfs*18 | Frame Shift Ins (INS) | VAF 114/341 reads (33%) | called by mutect2, pindel, varscan2
- UBXN7 | c.116del p.N39Tfs*87 | Frame Shift Del (DEL) | VAF 75/268 reads (28%) | called by mutect2, pindel, varscan2
- AASS | c.735C>G p.P245= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs1270710695, COSV62789294; called by muse, mutect2, varscan2
- ADAMTS20 | c.2310G>T p.G770= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV67128743; called by muse, mutect2, varscan2
- ARFGEF3 | c.387T>C p.D129= | Silent (SNP) | VAF 162/374 reads (43%) | catalogued as COSV52451971; called by muse, mutect2, varscan2
- ARID1B | c.3276C>G p.V1092= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV51652693; called by muse, mutect2, varscan2
- ATP10A | c.2481G>A p.L827= | Silent (SNP) | VAF 118/155 reads (76%) | catalogued as COSV63514801; called by muse, mutect2, varscan2
- GASK1B | c.1416T>A p.S472= | Silent (SNP) | VAF 60/71 reads (85%) | catalogued as COSV56705438; called by muse, mutect2, varscan2
- GLB1 | c.534G>A p.G178= | Silent (SNP) | VAF 207/387 reads (53%) | catalogued as rs928862880, COSV56562176; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KDELR1 | c.609A>G p.L203= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as COSV58101739; called by muse, mutect2, varscan2
- KY | c.7C>T p.L3= | Silent (SNP) | VAF 76/286 reads (27%) | catalogued as rs1313793591, COSV71016731; called by muse, mutect2, varscan2
- LONP1 | c.1512C>T p.F504= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs763432896, COSV100638737, COSV62260873; called by muse, mutect2, varscan2
- NRCAM | c.1428T>C p.C476= (on ENST00000379028 / NM_001371124.1; = p.C470= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 158/325 reads (49%) | catalogued as COSV61032702; called by muse, mutect2, varscan2
- NSUN5 | c.7C>T p.L3= | Silent (SNP) | VAF 131/246 reads (53%) | catalogued as rs1554542424, COSV53091624; called by muse, mutect2, varscan2
- OR13D1 | c.996T>A p.A332= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV59513625; called by muse, mutect2, varscan2
- OR2W1 | c.618T>A p.I206= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as COSV65851461; called by muse, mutect2, varscan2
- PKN3 | c.1491G>A p.L497= | Silent (SNP) | VAF 99/251 reads (39%) | catalogued as COSV52575368; called by muse, mutect2, varscan2
- SCN8A | c.225C>T p.G75= | Silent (SNP) | VAF 112/231 reads (48%) | catalogued as COSV61977892; called by muse, mutect2, varscan2
- SLC22A14 | c.327C>T p.H109= | Silent (SNP) | VAF 19/267 reads (7%) | catalogued as COSV56196851, COSV99828227; called by muse, mutect2
- TLR1 | c.1047G>T p.P349= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV58303432; called by muse, mutect2, varscan2
- TRMT61B | c.243T>C p.C81= | Silent (SNP) | VAF 140/283 reads (49%) | catalogued as rs889148463, COSV60257667; called by muse, mutect2, varscan2
- YIPF7 | c.438T>C p.N146= | Silent (SNP) | VAF 51/90 reads (57%) | catalogued as rs780560919, COSV60656244; called by muse, mutect2, varscan2
- ZNF462 | c.1026T>G p.S342= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV52932528; called by muse, mutect2, varscan2
- ZNF831 | c.784A>C p.R262= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV64038233; called by muse, mutect2
- CPLANE1 | c.*3202G>T | 3'UTR (SNP) | VAF 126/520 reads (24%) | catalogued as COSV57054794; called by muse, mutect2, varscan2
- DPP6 | c.627+20940G>A | Intron (SNP) | VAF 140/280 reads (50%) | catalogued as COSV100123227; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129614T>A | Intron (SNP) | VAF 27/317 reads (9%) | catalogued as COSV56742632; called by muse, mutect2
- RUSC1 | c.-86-341A>G | Intron (SNP) | VAF 90/574 reads (16%) | catalogued as COSV52738545; called by muse, mutect2, varscan2
